Somatic mutation profile of tumor specimen TARGET-30-PATPHR-01A (aliquot TARGET-30-PATPHR-01A-01D) from TARGET case TARGET-30-PATPHR, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.0 years (1,471 days).
Specimen TARGET-30-PATPHR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885441e6-72d6-45cb-8814-c0cbef8133ce.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATPHR-10A (Blood Derived Normal), aliquot TARGET-30-PATPHR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f28ab8c1-5404-4f15-bbaa-6376a725f409

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Nonsense Mutation 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.12348G>C p.E4116D | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MAP3K6 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- ARID1B | c.3096+879A>T | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- IL31RA | c.*273A>T | 3'UTR (SNP) | VAF 46/153 reads (30%) | catalogued as COSV61697790; called by muse, mutect2, varscan2
- PTPRT | c.*2188G>A | 3'UTR (SNP) | VAF 75/188 reads (40%) | catalogued as COSV62037814; called by muse, mutect2, varscan2
